Somatic mutation profile of tumor specimen TCGA-DS-A7WH-01A (aliquot TCGA-DS-A7WH-01A-22D-A351-09) from TCGA case TCGA-DS-A7WH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 34.6 years (12,644 days).
Specimen TCGA-DS-A7WH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5b3bbe1-e4c7-40a0-92e0-ad6ad28ba2f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A7WH-10A (Blood Derived Normal), aliquot TCGA-DS-A7WH-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baa5d58c-e5e0-4293-99a3-369680d73799

The open-access MAF lists 100 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Nonsense Mutation 7, 3'UTR 2, Intron 2, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.2908G>A p.V970I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1443019738; called by muse, mutect2, varscan2
- ARID1A | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99055332; called by muse, mutect2, varscan2
- CENATAC | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs782494985, COSV57722953; called by muse, mutect2, varscan2
- CNTNAP1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1433318265; called by muse, mutect2, varscan2
- DDX5 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1288793124; called by muse, mutect2, varscan2
- DOK3 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs756794198, COSV57254673; called by muse, mutect2, varscan2
- DYNC1I2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.945); catalogued as rs201120526; called by muse, mutect2, varscan2
- FAM50A | c.649-1G>A p.X217_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV50133663; called by muse, mutect2, varscan2
- FRMPD2 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.367); catalogued as rs766819950, COSV59719933; called by muse, mutect2, varscan2
- HDAC7 | c.1897C>A p.H633N (on ENST00000427332; = p.H672N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99315316; called by muse, mutect2, varscan2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2, varscan2
- ITCH | c.787A>C p.T263P (on ENST00000262650 / NM_001257137.3; = p.T222P on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1284234404; called by muse, mutect2, varscan2
- LRIT1 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1461334692, COSV64513576; called by muse, mutect2, varscan2
- MAP1A | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100287848; called by mutect2, varscan2
- MBD6 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs765647683, COSV63073310; called by muse, mutect2, varscan2
- MFN2 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs146092040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs754506439; called by muse, mutect2, varscan2
- MTMR4 | c.2882C>T p.S961L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.216); catalogued as rs376612881, COSV60199274; called by muse, mutect2, varscan2
- NINL | c.3439G>C p.D1147H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54010851; called by muse, mutect2, varscan2
- NRAP | c.4618C>T p.R1540W (on ENST00000359988 / NM_001322945.2; = p.R1505W on NM_006175.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs754598669, COSV63494052; called by muse, mutect2, varscan2
- OR10S1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs748991297, COSV101602483, COSV73342652, COSV73342905; called by muse, mutect2, varscan2
- PCDHA7 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1554134295; called by muse, mutect2, varscan2
- PCDHA8 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV65336089; called by muse, mutect2, varscan2
- PCDHGC5 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV52743075; called by muse, mutect2, varscan2
- PPP1R3A | c.2991C>A p.F997L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99494569; called by muse, mutect2, varscan2
- PRELID2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs1174326340, COSV100597044; called by muse, mutect2, varscan2
- RBM48 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as COSV56003904, COSV99719989; called by muse, mutect2
- RP1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55124082; called by muse, mutect2, varscan2
- SDK2 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66185332; called by muse, mutect2, varscan2
- SYNE2 | c.18622C>T p.R6208C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377305355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D14 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs770100466; called by muse, mutect2, varscan2
- TLL2 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs1042524459, COSV63574297; called by muse, mutect2, varscan2
- TMEM135 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100449164; called by muse, mutect2, varscan2
- ZFP36L2 | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs761179005; called by muse, mutect2, varscan2
- ZNF621 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs374160688; called by muse, mutect2, varscan2
- ZNFX1 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs139657531; called by muse, mutect2, varscan2
- ZSWIM4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV54320289; called by muse, mutect2, varscan2
- ADAMTS20 | c.3789C>A p.C1263* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- ADGRG5 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ANGPTL1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2
- ANKRD12 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ANKRD12 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- ANKRD12 | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CLIP1 | c.3499C>T p.Q1167* (on ENST00000620786 / NM_001247997.1; = p.Q1156* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- DDX60L | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC17 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DST | c.14965del p.E4989Kfs*9 (on ENST00000361203 / NM_001374722.1; = p.E2577Kfs*9 on NM_015548.5) | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- ENOX1 | c.1480A>C p.K494Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GDPD1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPR68 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-G | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISOC1 | c.312C>G p.L104= | Splice Region (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- KIFC1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAP1A | c.1281G>T p.R427S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MAP1A | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MAP1A | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MYO9A | c.7502A>C p.K2501T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NAA15 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NBAS | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PLA2G12A | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PUS7 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SEZ6 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SFMBT2 | c.1457G>C p.R486T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SLC30A6 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPOUT1 | c.16A>T p.R6W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMEM182 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM63 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIT1 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- TRPM4 | c.3382C>T p.H1128Y | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- USP34 | c.4912C>A p.H1638N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZMAT1 | c.762A>T p.R254S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF829 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARFGEF1 | c.3220C>A p.R1074= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- CAPN6 | c.306C>T p.P102= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100136677; called by muse, mutect2, varscan2
- CASZ1 | c.4449C>T p.R1483= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs969487418; called by muse, mutect2, varscan2
- CCDC137 | c.243C>T p.I81= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs574701572; called by muse, varscan2
- CFAP206 | c.1137G>A p.V379= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- CHD5 | c.5349G>A p.E1783= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1384475411; called by muse, mutect2, varscan2
- COL6A6 | c.24C>T p.L8= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs370873490; called by muse, mutect2, varscan2
- ESPN | c.2130G>A p.A710= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100911297; called by muse, mutect2, varscan2
- FCGRT | c.849G>A p.A283= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs761660729, COSV54543872; called by muse, mutect2
- GJB5 | c.30G>A p.L10= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs778464168; called by muse, mutect2, varscan2
- KYAT3 | c.337C>T p.L113= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- MAP1B | c.1956G>A p.E652= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV57105792; called by muse, mutect2, varscan2
- MYCBPAP | c.543C>T p.A181= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100087482; called by muse, mutect2, varscan2
- PNPLA5 | c.72C>T p.H24= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs748898005, COSV99336465; called by muse, varscan2
- RPGRIP1 | c.2235C>T p.F745= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs767808334, COSV52852748; called by muse, mutect2, varscan2
- SETD1A | c.3055C>T p.L1019= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SRP72 | c.1287C>T p.F429= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV61377358; called by muse, mutect2, varscan2
- SRRM4 | c.1677G>A p.R559= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV57428731; called by muse, mutect2, varscan2
- TBX22 | c.351G>A p.A117= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- TNFSF15 | c.435A>G p.G145= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1416694839, COSV65010951; called by muse, mutect2, varscan2
- TRIM42 | c.633C>T p.H211= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1475368922, COSV53881710; called by muse, mutect2, varscan2
- TTN | c.37749G>A p.L12583= (on ENST00000591111; = p.L5159= on NM_003319.4) | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- WDR36 | c.144G>A p.L48= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- KHK | c.210-298T>C | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as rs765447076; called by muse, mutect2, varscan2
- LRP1 | c.841+4233C>T | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as rs752240731; called by muse, mutect2, varscan2
- NR3C1 | c.*2522C>T | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- RBM15 | c.*52G>A | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
